Somatic mutation profile of tumor specimen TCGA-ET-A3BS-01A (aliquot TCGA-ET-A3BS-01A-11D-A202-08) from TCGA case TCGA-ET-A3BS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.2 years (15,421 days).
Specimen TCGA-ET-A3BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7609cb95-7da2-4e69-99f9-6bf9c7718e9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BS-10A (Blood Derived Normal), aliquot TCGA-ET-A3BS-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7871eb-1869-4dc0-adb6-fcf7d1365b5c

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- EXPH5 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV56206495; called by muse, mutect2
- LPL | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200669137, COSV60932364; called by muse, mutect2, varscan2
- LIFR | c.669C>T p.Y223= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs867567100, COSV54696740; called by muse, mutect2, varscan2
- NPAS2 | c.1527A>G p.L509= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV59560772; called by muse, mutect2
- SLC25A3 | c.345T>G p.G115= (on ENST00000228318 / NM_005888.3; = p.G114= on NM_002635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV51847059; called by muse, mutect2, varscan2
- SLC25A42 | c.426A>G p.G142= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as rs752187142; called by muse, mutect2, varscan2
